Gene-level copy-number profile of tumor specimen TCGA-10-0936-01A from TCGA case TCGA-10-0936, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 69.7 years (25,454 days).
Specimen TCGA-10-0936-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.0eb9976b-f75f-4763-8954-bdba8c9047a1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-10-0936-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d5e0f306-b159-4116-9865-ef85106c356d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 3; copy number 2: 9,107; copy number 3: 23,192; copy number 4: 9,974; copy number 5: 5,388; copy number 6: 5,582; copy number 7: 3,867; copy number 8: 771; copy number 9: 133; copy number 10: 1,651; copy number 12: 21; copy number 16: 21; copy number 17: 53; copy number 25: 49.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-10-0936-01): tumor purity 0.89, ploidy 3.76, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 6,566 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:227,918,656–248,919,946, 524 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr3:4,490,891–4,985,323, 7 genes, copy number 8: ITPR1-DT, ITPR1, EGOT, AC018816.2, AC018816.1, BHLHE40-AS1, BHLHE40.
- chr3:149,162,410–149,465,201, 13 genes, copy number 8 (within-gene range 6–8): CP, AC093001.2, CPHL1P, AC093001.1, TM4SF18, AC073522.1, TM4SF1, TM4SF1-AS1, AC108751.4, AC108751.2, AC108751.3, FKBP1AP4, AC108751.1.
- chr5:58,198–56,606,232, 825 genes, copy number 7 (broad region; genes not listed).
- chr5:93,617,725–94,111,699, 1 gene, copy number 7 (within-gene range 6–7): FAM172A.
- chr5:93,790,505–181,342,213, 1,584 genes, copy number 7 (broad region; genes not listed).
- chr8:19,375,128–19,852,083, 4 genes, copy number 7: AC068880.4, CSGALNACT1, AC090541.1, INTS10.
- chr8:21,690,398–21,812,357, 1 gene, copy number 8 (within-gene range 4–8): GFRA2.
- chr8:32,647,202–145,066,685, 1,760 genes, copy number 7–12 (broad region; genes not listed).
- chr11:74,397,549–74,485,742, 1 gene, copy number 7 (within-gene range 4–7): AP001372.1.
- chr11:74,454,841–74,669,117, 8 genes, copy number 7 (within-gene range 5–7): KCNE3, AP001372.3, CYCSP27, AP001372.4, LIPT2, AP001372.2, POLD3, RANP3.
- chr17:48,377,262–48,647,023, 21 genes, copy number 9: AC036222.2, U3, AC036222.1, Y_RNA, HOXB1, HOXB2, HOXB-AS1, HOXB3, HOXB-AS3, HOXB-AS2, HOXB4, AC103702.1, MIR10A, HOXB5, HOXB6, HOXB7, HOXB8, HOXB9, HOXB-AS4, MIR196A1, AC103702.2.
- chr19:10,133,342–10,923,075, 44 genes, copy number 10: DNMT1, S1PR2, MIR4322, MRPL4, AC011511.2, AC011511.3, ICAM1, AC011511.5, ICAM4, ICAM5, ZGLP1, AC011511.1, FDX2, AC011511.4, RAVER1, AC114271.1, ICAM3, TYK2, CDC37, MIR1181, PDE4A, KEAP1, AC011461.1, S1PR5, ATG4D, RNU7-140P, MIR1238, KRI1, CDKN2D, AP1M2, AC011475.1, SLC44A2, ILF3-DT, ILF3, QTRT1, DNM2, MIR638, MIR4748, MIR199A1, MIR6793, TMED1, C19orf38, HIKESHIP2, CARM1.
- chr19:12,995,475–15,332,545, 102 genes, copy number 17–25 (within-gene range 3–25) (broad region; genes not listed).
- chr19:18,990,888–19,252,233, 11 genes, copy number 10 (within-gene range 2–10): SUGP2, ARMC6, SLC25A42, TMEM161A, MEF2B, BORCS8-MEF2B, BORCS8, RFXANK, NR2C2AP, NCAN, RNU6-1028P.
- chr19:27,638,483–32,073,809, 83 genes, copy number 8–16 (broad region; genes not listed).
- chr20:87,250–64,313,132, 1,458 genes, copy number 7–8 (broad region; genes not listed).
- chr21:17,593,653–26,573,286, 112 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr22:41,367,333–41,544,606, 7 genes, copy number 7: TEF, RNU6-495P, AL008582.1, TOB2, ACO2, PHF5A, POLR3H.

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
